Somatic mutation profile of tumor specimen 0DOJXS from CCDI case PBCCDJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.9 years (5,068 days).
Specimen 0DOJXS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b1a10bc-f768-4732-97a8-71cef605c5db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOJUS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92bfbb2e-ed73-46de-86fe-5891bf076996

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 4, Nonsense Mutation 2, Silent 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 28/801 reads (3%) | catalogued as COSV59989381; called by muse, mutect2
- MUC12 | c.8076del p.T2693Pfs*93 (on ENST00000379442; = p.T2550Pfs*93 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs1554342786; called by mutect2, varscan2
- MYO7B | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 52/494 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs780397636, COSV104432202; called by muse, mutect2, varscan2
- NDUFAF7 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 180/777 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs760279124, COSV50019218; called by muse, mutect2, varscan2
- CKAP5 | c.2867A>T p.N956I | Missense Mutation (SNP) | VAF 125/522 reads (24%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- FER1L6 | c.5042T>A p.L1681* | Nonsense Mutation (SNP) | VAF 44/812 reads (5%) | called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 54/1310 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- MYO1A | c.1832A>T p.Y611F | Missense Mutation (SNP) | VAF 27/848 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CNTRL | c.5007A>G p.Q1669= | Silent (SNP) | VAF 60/803 reads (7%) | catalogued as rs761995459; called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 50/998 reads (5%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 18/178 reads (10%) | called by muse, varscan2
- NDUFB2 | c.-37G>T | 5'UTR (SNP) | VAF 30/136 reads (22%) | called by muse, mutect2, varscan2
